Somatic mutation profile of tumor specimen TCGA-FB-AAPU-01A (aliquot TCGA-FB-AAPU-01A-31D-A40W-08) from TCGA case TCGA-FB-AAPU, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 41.4 years (15,129 days).
Specimen TCGA-FB-AAPU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b5853cd7-860d-4cb1-b097-917c94fdd411.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FB-AAPU-11A (Solid Tissue Normal), aliquot TCGA-FB-AAPU-11A-12D-A40W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ead9ae30-d230-46a0-940e-67a8c1cccb20

The open-access MAF lists 87 somatic variants for this specimen: 67 protein-altering or splice-affecting, 19 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 57, Silent 19, Splice Site 3, Frame Shift Del 3, In Frame Ins 1, Nonsense Mutation 1, In Frame Del 1, Frame Shift Ins 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRCA2 | c.8145del p.V2716Wfs*17 | Frame Shift Del (DEL) | VAF 123/470 reads (26%) | catalogued as rs1135401923; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- KRAS | c.34G>C p.G12R | Missense Mutation (SNP) | VAF 53/155 reads (34%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACSL4 | c.813C>A p.D271E (on ENST00000340800 / NM_022977.2; = p.D230E on NM_004458.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 68/463 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100538421; called by muse, mutect2, varscan2
- ADAMTS3 | c.735G>C p.M245I | Missense Mutation (SNP) | VAF 26/803 reads (3%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV99710649; called by muse, mutect2
- ADRA1A | c.397C>T p.R133C | Missense Mutation (SNP) | VAF 52/217 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs968763557, COSV52369597; called by muse, mutect2, varscan2
- AMBP | c.330C>G p.H110Q | Missense Mutation (SNP) | VAF 99/341 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.617); catalogued as COSV99468933; called by muse, mutect2, varscan2
- ASTN2 | c.536G>T p.S179I | Missense Mutation (SNP) | VAF 58/459 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.36); catalogued as rs751867538, COSV100525924; called by muse, mutect2, varscan2
- BIK | c.325G>C p.D109H | Missense Mutation (SNP) | VAF 147/288 reads (51%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.866); catalogued as COSV99295624; called by muse, mutect2, varscan2
- C1QB | c.181+1G>A p.X61_splice | Splice Site (SNP) | VAF 22/40 reads (55%) | catalogued as CS1311832, COSV59246086; called by muse, mutect2, varscan2
- C2CD5 | c.1394G>T p.C465F | Missense Mutation (SNP) | VAF 18/214 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.735); catalogued as COSV100448592; called by muse, mutect2
- CABP1 | c.939+2T>C p.X313_splice (on ENST00000316803 / NM_001033677.1; = p.X110_splice on NM_004276.5) | Splice Site (SNP) | VAF 25/332 reads (8%) | catalogued as COSV99974599; called by muse, mutect2
- CCDC58 | c.343G>A p.E115K | Missense Mutation (SNP) | VAF 64/211 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52248036, COSV99360440; called by muse, mutect2, varscan2
- CCNL1 | c.1496G>A p.R499H | Missense Mutation (SNP) | VAF 129/415 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.277); catalogued as rs202095674; called by muse, mutect2, varscan2
- CDH4 | c.2612A>G p.E871G | Missense Mutation (SNP) | VAF 26/196 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100848631; called by muse, mutect2, varscan2
- CDH8 | c.10C>T p.R4W | Missense Mutation (SNP) | VAF 40/362 reads (11%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.99); catalogued as COSV54872322; called by muse, mutect2, varscan2
- CPEB1 | c.1647C>A p.S549R (on ENST00000617958; = p.S484R on NM_030594.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 232/415 reads (56%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.642); catalogued as COSV99917574; called by muse, mutect2, varscan2
- CYP8B1 | c.10T>G p.W4G | Missense Mutation (SNP) | VAF 63/151 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.779); catalogued as COSV100296087; called by muse, mutect2, varscan2
- DCST2 | c.1525C>A p.L509I | Missense Mutation (SNP) | VAF 102/474 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0.377); catalogued as COSV99791762; called by muse, mutect2, varscan2
- DGKK | c.1556C>A p.S519Y | Missense Mutation (SNP) | VAF 9/104 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV101052938; called by muse, mutect2
- EXTL3 | c.1913C>A p.P638H | Missense Mutation (SNP) | VAF 77/307 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99593851; called by muse, mutect2, varscan2
- FIP1L1 | c.188G>C p.G63A | Missense Mutation (SNP) | VAF 60/154 reads (39%) | SIFT tolerated (0.53); PolyPhen benign (0.189); catalogued as COSV100184323; called by muse, mutect2, varscan2
- GIMAP1 | c.505A>C p.T169P | Missense Mutation (SNP) | VAF 100/476 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV100212044; called by muse, mutect2, varscan2
- H2AP | c.110A>T p.Q37L | Missense Mutation (SNP) | VAF 66/192 reads (34%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.919); catalogued as COSV100586916, COSV61910840; called by muse, mutect2, varscan2
- HACE1 | c.2252G>C p.R751T | Missense Mutation (SNP) | VAF 14/200 reads (7%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.966); catalogued as COSV99493482; called by muse, mutect2
- HDGFL2 | c.1790A>G p.D597G | Missense Mutation (SNP) | VAF 57/189 reads (30%) | SIFT tolerated, low confidence (0.06); catalogued as COSV100012175; called by muse, mutect2, varscan2
- INTS9 | c.10-1G>T p.X4_splice | Splice Site (SNP) | VAF 32/132 reads (24%) | catalogued as COSV101273824; called by muse, mutect2, varscan2
- ITSN2 | c.1442T>C p.I481T | Missense Mutation (SNP) | VAF 124/394 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV100743048; called by muse, varscan2
- JAKMIP2 | c.319C>G p.R107G | Missense Mutation (SNP) | VAF 487/969 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.099); catalogued as COSV54597684, COSV99507827; called by muse, mutect2, varscan2
- JOSD1 | c.474G>T p.K158N | Missense Mutation (SNP) | VAF 18/529 reads (3%) | SIFT tolerated (0.09); PolyPhen benign (0.026); catalogued as COSV99320114; called by muse, mutect2
- KCNC1 | c.1396C>A p.L466M | Missense Mutation (SNP) | VAF 91/276 reads (33%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.883); catalogued as COSV99788980; called by muse, mutect2, varscan2
- KCNG3 | c.664G>C p.G222R | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT tolerated (0.53); PolyPhen benign (0.125); catalogued as rs375643888, COSV100044889; called by muse, varscan2
- KCNQ3 | c.1086A>T p.Q362H | Missense Mutation (SNP) | VAF 171/429 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV101195852; called by muse, mutect2, varscan2
- KIAA1210 | c.3693G>T p.K1231N | Missense Mutation (SNP) | VAF 26/127 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.221); catalogued as COSV101274020; called by muse, mutect2, varscan2
- KNSTRN | c.640C>T p.R214W | Missense Mutation (SNP) | VAF 115/342 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.648); catalogued as rs761530012, COSV99991796; called by muse, mutect2, varscan2
- L3MBTL2 | c.1069T>A p.Y357N | Missense Mutation (SNP) | VAF 135/320 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99345775; called by muse, mutect2, varscan2
- LSM14B | c.386G>A p.S129N | Missense Mutation (SNP) | VAF 47/128 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.156); catalogued as COSV99444030; called by muse, mutect2, varscan2
- MEOX1 | c.454A>G p.R152G | Missense Mutation (SNP) | VAF 24/965 reads (2%) | SIFT deleterious (0.04); PolyPhen benign (0.075); catalogued as COSV100233713; called by muse, mutect2
- MYLK | c.3395C>T p.T1132M | Missense Mutation (SNP) | VAF 161/477 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.176); catalogued as rs202025561, COSV60606474; called by muse, mutect2, varscan2
- NOS3 | c.1627C>T p.R543W | Missense Mutation (SNP) | VAF 187/430 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.976); catalogued as rs762597577, COSV52494946; called by muse, mutect2, varscan2
- OR56A3 | c.437T>A p.V146D | Missense Mutation (SNP) | VAF 159/491 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.189); catalogued as COSV100290117; called by muse, mutect2, varscan2
- PAPPA2 | c.2351G>A p.R784Q | Missense Mutation (SNP) | VAF 265/666 reads (40%) | SIFT tolerated (0.82); PolyPhen benign (0.037); catalogued as rs758207581, COSV62783224; called by muse, mutect2, varscan2
- PLK2 | c.2042T>G p.L681* | Nonsense Mutation (SNP) | VAF 10/326 reads (3%) | catalogued as COSV57107791, COSV99955908; called by muse, mutect2
- PLK4 | c.2694G>C p.W898C | Missense Mutation (SNP) | VAF 86/296 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.272); catalogued as COSV54638376, COSV99584531; called by muse, mutect2, varscan2
- PTPRB | c.344G>A p.G115D | Missense Mutation (SNP) | VAF 40/122 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.676); catalogued as COSV99316857; called by muse, mutect2, varscan2
- RND3 | c.731T>C p.M244T | Missense Mutation (SNP) | VAF 99/187 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.663); catalogued as COSV99811948; called by muse, mutect2, varscan2
- SDK1 | c.5245G>A p.E1749K | Missense Mutation (SNP) | VAF 22/334 reads (7%) | SIFT tolerated (0.27); PolyPhen benign (0.082); catalogued as rs1364713936, COSV67357225; called by muse, mutect2
- SHROOM4 | c.907G>C p.V303L | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.01); catalogued as COSV99173177; called by muse, mutect2, varscan2
- SPP2 | c.169A>T p.S57C | Missense Mutation (SNP) | VAF 102/239 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV99394483; called by muse, mutect2, varscan2
- TEX10 | c.1672C>G p.Q558E | Missense Mutation (SNP) | VAF 70/185 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.708); catalogued as COSV100887665; called by muse, mutect2, varscan2
- THOC5 | c.1475A>G p.Q492R | Missense Mutation (SNP) | VAF 77/788 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV100803512; called by muse, mutect2
- TIMM10B | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 40/177 reads (23%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs1471416060, COSV99601470; called by muse, mutect2, varscan2
- TMEM52 | c.281C>T p.A94V | Missense Mutation (SNP) | VAF 72/129 reads (56%) | SIFT tolerated (0.12); PolyPhen benign (0.396); catalogued as COSV100205508; called by muse, mutect2, varscan2
- TMPRSS3 | c.47G>A p.R16Q | Missense Mutation (SNP) | VAF 55/161 reads (34%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.12); catalogued as rs369418733; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TMPRSS6 | c.1778G>T p.C593F | Missense Mutation (SNP) | VAF 20/432 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1038543194, COSV100695595; called by muse, mutect2
- TRMT2A | c.382G>A p.V128I | Missense Mutation (SNP) | VAF 65/231 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs200653246, COSV99349876; called by muse, mutect2, varscan2
- TSSK1B | c.874C>T p.R292W | Missense Mutation (SNP) | VAF 50/136 reads (37%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.42); catalogued as rs369630791; called by muse, mutect2, varscan2
- TULP3 | c.787G>A p.E263K | Missense Mutation (SNP) | VAF 56/177 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as COSV101237494; called by muse, mutect2, varscan2
- XRN1 | c.2858T>G p.V953G | Missense Mutation (SNP) | VAF 67/253 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as COSV99377584; called by muse, mutect2, varscan2
- ZNF600 | c.697C>A p.L233I | Missense Mutation (SNP) | VAF 40/619 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100592932; called by muse, mutect2
- ZNF608 | c.1318T>A p.S440T | Missense Mutation (SNP) | VAF 12/339 reads (4%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV100101364; called by muse, mutect2
- ZZZ3 | c.2706C>G p.N902K | Missense Mutation (SNP) | VAF 65/215 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100890258; called by muse, mutect2, varscan2
- AAMP | c.348_353delinsGGCTTTGTC p.F117_V118delinsALS | In Frame Ins (INS) | VAF 31/345 reads (9%) | called by pindel, varscan2*
- ABCA1 | c.2030_2046del p.D677Vfs*2 | Frame Shift Del (DEL) | VAF 47/215 reads (22%) | called by mutect2, pindel, varscan2
- MYH14 | c.1643dup p.G549Wfs*8 | Frame Shift Ins (INS) | VAF 19/82 reads (23%) | called by mutect2, pindel, varscan2
- PRSS1 | c.324_326del p.I108del | In Frame Del (DEL) | VAF 264/654 reads (40%) | called by pindel, varscan2
- SUCO | c.3104_3114del p.N1035Ifs*2 | Frame Shift Del (DEL) | VAF 54/363 reads (15%) | called by mutect2, pindel, varscan2
- TMEM53 | c.376C>G p.L126V | Missense Mutation (SNP) | VAF 7/178 reads (4%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.97); called by muse, mutect2
- ABCA4 | c.114C>G p.V38= | Silent (SNP) | VAF 66/396 reads (17%) | catalogued as COSV100933080; called by muse, mutect2, varscan2
- ADAMTS3 | c.255G>C p.T85= | Silent (SNP) | VAF 73/236 reads (31%) | catalogued as COSV99710650; called by muse, mutect2, varscan2
- AKAP8 | c.849G>A p.R283= | Silent (SNP) | VAF 31/137 reads (23%) | catalogued as COSV54103262; called by muse, mutect2, varscan2
- B4GALNT2 | c.549C>T p.R183= | Silent (SNP) | VAF 14/41 reads (34%) | catalogued as rs1253154784, COSV100302497; called by muse, mutect2, varscan2
- CASS4 | c.2127C>T p.V709= | Silent (SNP) | VAF 88/256 reads (34%) | catalogued as rs372142142; called by muse, mutect2, varscan2
- CCIN | c.1326C>T p.V442= | Silent (SNP) | VAF 80/286 reads (28%) | catalogued as rs777875137, COSV58724426; called by muse, mutect2, varscan2
- DAAM2 | c.2670G>A p.A890= | Silent (SNP) | VAF 13/60 reads (22%) | catalogued as rs370996980; called by muse, varscan2
- FH | c.729T>C p.T243= | Silent (SNP) | VAF 147/295 reads (50%) | catalogued as COSV100844999; called by muse, mutect2, varscan2
- LIMCH1 | c.369G>A p.L123= | Silent (SNP) | VAF 67/205 reads (33%) | catalogued as COSV100573645; called by muse, mutect2, varscan2
- MCOLN2 | c.687C>T p.G229= | Silent (SNP) | VAF 15/216 reads (7%) | catalogued as COSV99393721; called by muse, mutect2
- MISP | c.723C>T p.N241= | Silent (SNP) | VAF 25/101 reads (25%) | catalogued as rs754864934, COSV53119471; called by muse, mutect2, varscan2
- PAPPA2 | c.1525T>C p.L509= | Silent (SNP) | VAF 69/314 reads (22%) | catalogued as rs1480404981, COSV100866684; called by muse, mutect2, varscan2
- PCDHGA10 | c.822C>T p.D274= | Silent (SNP) | VAF 8/127 reads (6%) | catalogued as COSV53924979; called by muse, mutect2
- PXDN | c.2538C>T p.H846= | Silent (SNP) | VAF 37/102 reads (36%) | catalogued as COSV99412884; called by muse, mutect2, varscan2
- RNF128 | c.84C>T p.A28= | Silent (SNP) | VAF 11/37 reads (30%) | catalogued as COSV99718053; called by muse, mutect2, varscan2
- SIPA1L3 | c.1731G>T p.G577= | Silent (SNP) | VAF 93/285 reads (33%) | catalogued as COSV99727977; called by muse, mutect2, varscan2
- STEAP3 | c.936C>T p.C312= | Silent (SNP) | VAF 72/133 reads (54%) | catalogued as rs145832236; called by muse, mutect2, varscan2
- TOP3B | c.1455G>A p.E485= | Silent (SNP) | VAF 14/258 reads (5%) | catalogued as COSV100592424; called by muse, mutect2
- UCP3 | c.54G>A p.L18= | Silent (SNP) | VAF 44/136 reads (32%) | catalogued as COSV100012920; called by muse, mutect2, varscan2
- POLA1 | c.2947-20888C>T | Intron (SNP) | VAF 149/431 reads (35%) | catalogued as rs756349313; called by muse, mutect2, varscan2
